Somatic mutation profile of tumor specimen TCGA-66-2783-01A (aliquot TCGA-66-2783-01A-01D-1267-08) from TCGA case TCGA-66-2783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-66-2783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96294133-3c78-47ca-a37d-82ef6e284a59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2783-11A (Solid Tissue Normal), aliquot TCGA-66-2783-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74cf00e0-c6d9-46ee-baf2-b82334e930e8

The open-access MAF lists 254 somatic variants for this specimen: 202 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 45, Nonsense Mutation 16, Frame Shift Del 6, Intron 4, Splice Site 4, Splice Region 3, In Frame Del 2, RNA 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 47/112 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 70/189 reads (37%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1333-2A>G p.X445_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | hotspot (GDC flag); catalogued as rs1555286503, CS030552, COSV57301529, COSV57304999, COSV57326295; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/133 reads (33%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.614T>G p.L205* | Nonsense Mutation (SNP) | VAF 74/327 reads (23%) | catalogued as COSV53788675; called by muse, varscan2
- ABCC12 | c.3185A>G p.Y1062C | Missense Mutation (SNP) | VAF 156/589 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60912783; called by muse, mutect2, varscan2
- ABCG8 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV55391792; called by muse, mutect2, varscan2
- ABI3BP | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 145/231 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1294019384, COSV52532282; called by muse, mutect2, varscan2
- ACADM | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs1553123872, CM119108, COSV57714289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM22 | c.2001G>T p.R667S | Missense Mutation (SNP) | VAF 90/360 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV55973369, COSV99716096; called by muse, mutect2, varscan2
- AFF4 | c.1332T>G p.S444R | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54793159; called by muse, mutect2, varscan2
- AHNAK | c.11557G>A p.E3853K | Missense Mutation (SNP) | VAF 251/819 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as COSV57208857; called by muse, mutect2, varscan2
- AMY1C | c.960T>A p.H320Q | Missense Mutation (SNP) | VAF 75/606 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100915214; called by muse, mutect2, varscan2
- ANK2 | c.3037A>T p.R1013* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV52153576; called by muse, mutect2, varscan2
- ARFGEF1 | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51605561; called by muse, mutect2, varscan2
- ARMC4 | c.467A>T p.K156I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV53464053; called by muse, mutect2, varscan2
- ASNS | c.984A>G p.I328M | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51551361; called by muse, mutect2, varscan2
- BBX | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 144/1024 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV57881717; called by muse, mutect2, varscan2
- BRD7 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67158479, COSV67158503; called by muse, mutect2, varscan2
- BTBD6 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs140283852; called by muse, mutect2, varscan2
- C11orf54 | c.865G>A p.E289K (on ENST00000331239; = p.E239K on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV58679793; called by muse, mutect2
- C20orf96 | c.563G>T p.S188I (on ENST00000360321 / NM_153269.3; = p.S187I on NM_080571.1) | Missense Mutation (SNP) | VAF 102/774 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV64403340; called by muse, varscan2
- CACNA1C | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1367643136, COSV59707183; called by muse, mutect2, varscan2
- CACNA1C | c.5336C>A p.P1779H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.751); catalogued as COSV59707190; called by muse, mutect2, varscan2
- CALN1 | c.16G>T p.V6L (on ENST00000329008 / NM_001017440.3; = p.V48L on NM_031468.4) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61125830; called by muse, mutect2, varscan2
- CATSPERG | c.2827C>G p.Q943E | Missense Mutation (SNP) | VAF 365/1297 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV53047503; called by muse, mutect2, varscan2
- CBX8 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53935924; called by muse, mutect2
- CDH11 | c.2312A>G p.Y771C | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51756693; called by muse, mutect2, varscan2
- CDH5 | c.1359T>A p.T453= | Splice Region (SNP) | VAF 43/168 reads (26%) | catalogued as COSV58516742; called by muse, mutect2, varscan2
- CDK7 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV56512772; called by muse, mutect2, varscan2
- CERT1 | c.2119T>A p.Y707N (on ENST00000405807 / NM_001130105.1; = p.Y579N on NM_005713.3) | Missense Mutation (SNP) | VAF 116/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54657055; called by muse, mutect2, varscan2
- CHST2 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 147/690 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV58885119; called by muse, mutect2, varscan2
- CLDN22 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 120/471 reads (25%) | catalogued as COSV60109202; called by muse, mutect2, varscan2
- CNDP1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 123/466 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs139749526; called by muse, mutect2, varscan2
- CNTNAP5 | c.2516G>C p.R839P | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1486365250, COSV70480019, COSV70498004; called by muse, mutect2, varscan2
- COL15A1 | c.2143G>T p.G715W | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66642911, COSV66650032; called by muse, mutect2, varscan2
- COL7A1 | c.8074G>T p.G2692C | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56476258; called by muse, mutect2, varscan2
- CSF1R | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753189846, COSV53832280; called by muse, mutect2, varscan2
- CSMD3 | c.7020-1G>A p.X2340_splice (on ENST00000297405 / NM_001363185.1; = p.X2236_splice on NM_052900.3) | Splice Site (SNP) | VAF 38/130 reads (29%) | catalogued as COSV52140919; called by muse, mutect2, varscan2
- CSMD3 | c.4657C>T p.Q1553* (on ENST00000297405 / NM_001363185.1; = p.Q1449* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 44/194 reads (23%) | catalogued as COSV52140936; called by muse, mutect2, varscan2
- CYP11B1 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.461); catalogued as COSV52824880, COSV52825943; called by muse, mutect2, varscan2
- DACT1 | c.310T>A p.L104M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60020068; called by muse, mutect2, varscan2
- DCST2 | c.140T>G p.V47G | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV55050849; called by muse, mutect2, varscan2
- DMGDH | c.2097G>A p.M699I | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54862196; called by muse, mutect2, varscan2
- DNAH9 | c.10660C>G p.H3554D | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV52342954; called by muse, mutect2, varscan2
- DOCK2 | c.2695C>A p.Q899K | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56951037; called by muse, mutect2, varscan2
- DOT1L | c.2659A>T p.S887C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV67108859; called by muse, mutect2, varscan2
- DUSP22 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs754658385, COSV60525393; called by muse, mutect2
- EIF4ENIF1 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 145/306 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57515333; called by muse, mutect2, varscan2
- EPB42 | c.1831C>T p.Q611* (on ENST00000441366 / NM_001114134.2; = p.Q641* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 95/330 reads (29%) | catalogued as COSV55749048; called by muse, mutect2, varscan2
- ERBB4 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201152419, COSV53517176; called by muse, mutect2, varscan2
- EXT2 | c.1877G>T p.C626F (on ENST00000343631; = p.C659F on NM_000401.3) | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59148221; called by muse, mutect2, varscan2
- FAM135B | c.665C>A p.S222* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | catalogued as COSV52715151; called by muse, mutect2, varscan2
- FAM47C | c.2718G>C p.M906I | Missense Mutation (SNP) | VAF 103/179 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV63725385; called by muse, mutect2, varscan2
- FAM71B | c.148A>T p.N50Y | Missense Mutation (SNP) | VAF 103/437 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV100261922, COSV57228273; called by muse, mutect2, varscan2
- FAM83D | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745414653, COSV54156947; called by muse, mutect2, varscan2
- FBN2 | c.2977C>G p.R993G | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52507505; called by muse, mutect2, varscan2
- FBN3 | c.3641A>G p.N1214S | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54456930; called by muse, mutect2, varscan2
- FCRL3 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV63840475; called by muse, mutect2, varscan2
- FGFRL1 | c.1072+1G>A p.X358_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs1274267456, COSV53256989; called by muse, mutect2, varscan2
- FUT3 | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV54605219, COSV54606578; called by muse, mutect2, varscan2
- FXR1 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 222/824 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59761970, COSV59762263; called by muse, mutect2, varscan2
- GAB2 | c.1240C>G p.R414G (on ENST00000361507 / NM_080491.3; = p.R376G on NM_012296.3) | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60866900; called by muse, mutect2, varscan2
- GABRA2 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62913439; called by muse, mutect2
- GAS2L3 | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 67/273 reads (25%) | catalogued as COSV57156679; called by muse, mutect2, varscan2
- GATA3 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60516939; called by muse, mutect2, varscan2
- GC | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56736556; called by muse, mutect2, varscan2
- GGT7 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs780547379, COSV60540261, COSV60540732, COSV60541939; called by muse, mutect2, varscan2
- GMPPA | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58006444, COSV58006861; called by muse, mutect2, varscan2
- GNL2 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV66079959; called by muse, mutect2, varscan2
- GOLGA3 | c.2366A>C p.K789T | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV52628246; called by muse, mutect2, varscan2
- GPR39 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV61416103; called by muse, mutect2, varscan2
- GPRIN2 | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV65400263, COSV65400709; called by muse, mutect2
- GPT2 | c.1508A>T p.K503M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV60837979; called by muse, mutect2, varscan2
- GRM8 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 82/467 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV58815323; called by muse, mutect2
- HMCN1 | c.6146G>A p.G2049E | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54888785; called by muse, mutect2, varscan2
- IGSF21 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 88/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52129504, COSV52141695; called by muse, mutect2, varscan2
- IKBKE | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs1447034305, COSV65624997; called by muse, mutect2, varscan2
- IKZF2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV59577444; called by muse, mutect2, varscan2
- INSC | c.1534+1G>C p.X512_splice | Splice Site (SNP) | VAF 26/114 reads (23%) | catalogued as COSV65409700; called by muse, mutect2, varscan2
- ITGAX | c.2881G>T p.G961* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV51643962; called by muse, varscan2
- KCNA6 | c.1285T>A p.Y429N | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.593); catalogued as COSV54974624; called by muse, mutect2, varscan2
- KCNQ3 | c.1600T>A p.F534I | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66467174; called by muse, varscan2
- KIFAP3 | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV63032380; called by muse, mutect2, varscan2
- KLHDC4 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as COSV54506948; called by muse, mutect2, varscan2
- KLHL18 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51744791; called by muse, mutect2, varscan2
- LEPR | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); catalogued as COSV60750692; called by muse, mutect2, varscan2
- LRRC10 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs768113431, COSV64060219; called by muse, mutect2, varscan2
- LRRC66 | c.1374C>G p.F458L | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58632876, COSV58635285; called by muse, mutect2, varscan2
- MACROD2 | c.1161A>T p.Q387H (on ENST00000642719; = p.Q359H on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV53964782; called by muse, mutect2, varscan2
- MANSC1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV67110834; called by muse, mutect2, varscan2
- MASP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV51458474; called by muse, varscan2
- MEPE | c.920C>A p.P307Q | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63072296; called by muse, mutect2, varscan2
- METAP2 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV51562905; called by muse, mutect2, varscan2
- MOXD1 | c.783C>G p.N261K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV60942993; called by muse, mutect2, varscan2
- MS4A2 | c.463A>T p.S155C | Missense Mutation (SNP) | VAF 91/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54011642; called by muse, mutect2, varscan2
- MUC16 | c.37115C>A p.P12372Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV67455953; called by muse, mutect2, varscan2
- MYH7 | c.4225G>A p.A1409T | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1381835227, COSV62517788; called by muse, mutect2, varscan2
- NALCN | c.4055C>A p.A1352D | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51926430; called by muse, varscan2
- NAV3 | c.2915C>A p.P972H | Missense Mutation (SNP) | VAF 78/386 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs751190776, COSV57103693, COSV99892259; called by muse, mutect2, varscan2
- NCK1 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 159/612 reads (26%) | catalogued as rs778198006, COSV56636632; called by muse, varscan2
- NCLN | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV55742240; called by muse, mutect2, varscan2
- NCOA2 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757931284, COSV71763730; called by muse, mutect2, varscan2
- NEUROD4 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 467/1828 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs763246217, COSV54471084; called by muse, mutect2, varscan2
- NFKBIL1 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV65990251; called by muse, mutect2, varscan2
- NTN4 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1208028292, COSV59218486, COSV59224927; called by muse, mutect2, varscan2
- NUAK2 | c.1604G>C p.R535P | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV65681124; called by mutect2, varscan2
- NUP133 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54569664, COSV99773033; called by muse, mutect2
- NUP160 | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 126/384 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV65853952; called by muse, varscan2
- NUP210L | c.4746C>G p.F1582L | Missense Mutation (SNP) | VAF 92/594 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55144779; called by muse, mutect2, varscan2
- OGDHL | c.2477A>T p.H826L | Missense Mutation (SNP) | VAF 133/490 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65101737; called by muse, mutect2, varscan2
- OR11A1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV65820835; called by muse, mutect2, varscan2
- OR2F2 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV68832657; called by muse, mutect2, varscan2
- OR4A47 | c.849A>T p.L283F | Missense Mutation (SNP) | VAF 163/620 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.172); catalogued as rs752115578, COSV71444884; called by muse, mutect2, varscan2
- OR4C6 | c.647A>T p.Y216F | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV58602519, COSV58603124; called by muse, mutect2, varscan2
- OR52N2 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV57676454; called by muse, mutect2, varscan2
- OR6B1 | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 91/366 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.82); catalogued as COSV68769957; called by muse, mutect2, varscan2
- OR8B2 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 87/411 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as COSV66664446, COSV66664729; called by muse, varscan2
- OTOL1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.119); catalogued as COSV60006364; called by muse, mutect2, varscan2
- PAIP1 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59085579; called by muse, mutect2, varscan2
- PAPPA2 | c.1126A>T p.M376L | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV62775670; called by muse, mutect2, varscan2
- PCDH11Y | c.3227C>A p.T1076K | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV53078044; called by muse, mutect2, varscan2
- PCDH19 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs1213619684, COSV55260160; called by muse, mutect2, varscan2
- PCDHGA11 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV53921593; called by muse, mutect2, varscan2
- PFKP | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as COSV66896460; called by muse, mutect2, varscan2
- PLEKHH3 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as COSV52217147; called by muse, mutect2, varscan2
- PPP6R3 | c.1198C>T p.L400F (on ENST00000393800 / NM_001352375.2; = p.L349F on NM_018312.5) | Missense Mutation (SNP) | VAF 101/375 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV55723638; called by muse, mutect2, varscan2
- PRAMEF10 | c.345A>G p.I115M | Missense Mutation (SNP) | VAF 80/846 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.406); catalogued as rs1322916076; called by muse, mutect2
- PRKCG | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV54725993; called by muse, mutect2, varscan2
- PRR18 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776929217, COSV59454345; called by muse, mutect2, varscan2
- RAB13 | c.123C>A p.I41= | Splice Region (SNP) | VAF 24/112 reads (21%) | catalogued as COSV63933655, COSV63933723; called by muse, mutect2, varscan2
- RGS20 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 105/441 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV52015217; called by muse, mutect2, varscan2
- RGS3 | c.1208C>T p.P403L (on ENST00000350696 / NM_001282923.2; = p.P291L on NM_017790.4) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs979115795, COSV100465076, COSV58279581; called by muse, mutect2, varscan2
- RHEB | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51262714, COSV51264201; called by muse, mutect2, varscan2
- RPS6KA1 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65175799; called by muse, mutect2, varscan2
- RTL9 | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 146/282 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV71825471; called by muse, mutect2, varscan2
- SBK2 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV60013708; called by muse, mutect2, varscan2
- SEC23B | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs17849992, COSV52719395; called by muse, mutect2, varscan2
- SENP1 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV50286997; called by muse, mutect2, varscan2
- SERPINA11 | c.1043A>T p.Q348L | Missense Mutation (SNP) | VAF 103/449 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV58241474; called by muse, mutect2, varscan2
- SERPINA4 | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54069358; called by muse, mutect2, varscan2
- SETD1A | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV52686305; called by muse, mutect2, varscan2
- SH3KBP1 | c.1607C>G p.T536S | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV65646583; called by muse, mutect2, varscan2
- SHCBP1 | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57646838; called by muse, mutect2, varscan2
- SMYD1 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV101352386; called by muse, mutect2, varscan2
- SORCS3 | c.1328A>G p.E443G | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV63806270; called by muse, mutect2, varscan2
- SORCS3 | c.2694C>A p.N898K | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV63794192; called by muse, mutect2, varscan2
- SPAG17 | c.4287G>T p.T1429= | Splice Region (SNP) | VAF 34/136 reads (25%) | catalogued as COSV60455899, COSV60460749; called by muse, mutect2, varscan2
- SPATA18 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs978014388, COSV54643071; called by muse, mutect2, varscan2
- SPATA18 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54643098; called by muse, mutect2, varscan2
- SPEG | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56666031; called by muse, mutect2, varscan2
- SPRY3 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 59/138 reads (43%) | catalogued as COSV57142334; called by muse, mutect2, varscan2
- SPTA1 | c.4017G>C p.E1339D | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63751060, COSV63758588; called by muse, mutect2, varscan2
- SPTA1 | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 164/334 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs1191816933, COSV63751063; called by muse, mutect2, varscan2
- SRRM2 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV57070840; called by muse, mutect2, varscan2
- SUGP1 | c.1402A>T p.M468L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV55920904; called by muse, mutect2, varscan2
- SULT1B1 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.113); catalogued as COSV60207118; called by muse, mutect2, varscan2
- SYNE1 | c.3410C>G p.S1137* (on ENST00000367255 / NM_182961.4; = p.S1144* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 6/159 reads (4%) | catalogued as COSV54943794; called by muse, mutect2
- SYT1 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 123/464 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV54040407; called by muse, mutect2, varscan2
- TAF1L | c.1937C>A p.A646E | Missense Mutation (SNP) | VAF 147/267 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.297); catalogued as COSV54259968; called by muse, mutect2, varscan2
- TAFA2 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV101353511, COSV69180456; called by muse, mutect2, varscan2
- TEC | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67404233; called by muse, mutect2, varscan2
- TET2 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54404805; called by muse, mutect2, varscan2
- TFAP2D | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 163/307 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs751663222, COSV50411488, COSV50441396; called by muse, mutect2, varscan2
- TG | c.5034G>C p.L1678F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as COSV55070790; called by muse, mutect2, varscan2
- TMC1 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52772023; called by muse, mutect2, varscan2
- TNNT2 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 296/816 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52661734; called by muse, mutect2, varscan2
- TRPM1 | c.4211C>A p.T1404K | Missense Mutation (SNP) | VAF 215/407 reads (53%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.006); catalogued as COSV56632755; called by muse, mutect2, varscan2
- TTC17 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV50007263; called by muse, mutect2
- TTN | c.93631G>A p.G31211S (on ENST00000591111; = p.G23787S on NM_003319.4) | Missense Mutation (SNP) | VAF 109/450 reads (24%) | PolyPhen benign (0.015); catalogued as COSV59964700; called by muse, mutect2, varscan2
- TTN | c.85553C>G p.P28518R (on ENST00000591111; = p.P21094R on NM_003319.4) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV59964754, COSV60057641; called by muse, mutect2, varscan2
- TTN | c.18101T>G p.I6034S (on ENST00000591111; = p.I5107S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | PolyPhen benign (0.326); catalogued as COSV59964789; called by muse, mutect2, varscan2
- TTN | c.6473G>T p.G2158V (on ENST00000591111; = p.G2112V on NM_003319.4) | Missense Mutation (SNP) | VAF 56/201 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV59964803, COSV60045227; called by muse, mutect2, varscan2
- UBQLN1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1452527441, COSV57407268; called by muse, mutect2, varscan2
- UNK | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV53140482; called by muse, mutect2, varscan2
- VWC2L | c.490C>G p.P164A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56968084; called by muse, mutect2, varscan2
- WDR46 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 248/453 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs34704405, COSV65842114; called by muse, mutect2, varscan2
- WDR88 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV63451012, COSV63452074; called by muse, mutect2, varscan2
- XIRP2 | c.9164G>C p.R3055P (on ENST00000628543; = p.R3230P on NM_152381.6) | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs780179120, COSV54691041; called by muse, mutect2, varscan2
- ZAN | c.1868C>G p.S623* | Nonsense Mutation (SNP) | VAF 40/163 reads (25%) | catalogued as COSV61807210; called by muse, mutect2, varscan2
- ZIC1 | c.1141A>G p.M381V | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV51552181; called by muse, mutect2, varscan2
- ZNF215 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53492420; called by muse, mutect2, varscan2
- ZNF304 | c.395T>G p.F132C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV56583841; called by muse, mutect2, varscan2
- ZNF330 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV53707070; called by muse, mutect2, varscan2
- ZNF496 | c.1042G>C p.D348H | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV54175502; called by muse, mutect2, varscan2
- ZNF696 | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV57524367; called by muse, varscan2
- ZNF700 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 80/284 reads (28%) | catalogued as COSV54311582; called by muse, mutect2, varscan2
- ZNF835 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV73379331; called by muse, mutect2, varscan2
- ZNF93 | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV59374813; called by muse, mutect2, varscan2
- ASAH2 | c.745A>T p.N249Y | Missense Mutation (SNP) | VAF 314/1176 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ATP10B | c.2294del p.G765Afs*13 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by pindel, varscan2
- B4GALT5 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- COG7 | c.1339_1341del p.C447del | In Frame Del (DEL) | VAF 53/203 reads (26%) | called by mutect2, pindel, varscan2
- DNAH9 | c.8566del p.Q2856Rfs*14 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- LRRTM1 | c.1292del p.G431Afs*72 | Frame Shift Del (DEL) | VAF 45/196 reads (23%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.948_953del p.R317_S318del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- MARCO | c.326dup p.A110Cfs*19 | Frame Shift Ins (INS) | VAF 14/97 reads (14%) | called by mutect2, pindel, varscan2
- MROH2B | c.4332del p.N1445Tfs*12 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- NR4A1 | c.1188del p.K397Rfs*139 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- SEMA5A | c.1907del p.G636Dfs*69 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- TPTE | c.78T>A p.S26R | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADGRB1 | c.3420C>T p.C1140= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs745611963, COSV60094017; called by muse, mutect2, varscan2
- AMER1 | c.1776G>A p.E592= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV57657714, COSV57666586; called by muse, mutect2, varscan2
- ANKRD34A | c.507G>A p.E169= | Silent (SNP) | VAF 101/290 reads (35%) | catalogued as COSV60160584; called by muse, mutect2, varscan2
- ANKRD6 | c.543T>A p.A181= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV60230247; called by muse, mutect2, varscan2
- ASIC2 | c.69C>A p.T23= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV63300077; called by muse, mutect2, varscan2
- ASMTL | c.1753C>A p.R585= | Silent (SNP) | VAF 59/191 reads (31%) | catalogued as rs371220130, COSV101188029, COSV67243316; called by muse, mutect2, varscan2
- BMS1 | c.2901G>A p.R967= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as rs186096151, COSV65733454; called by muse, mutect2, varscan2
- CARD19 | c.222G>A p.E74= | Silent (SNP) | VAF 105/210 reads (50%) | catalogued as COSV64935897; called by muse, mutect2, varscan2
- CCDC39 | c.708G>A p.K236= | Silent (SNP) | VAF 180/310 reads (58%) | catalogued as COSV56481305, COSV99870925; called by muse, mutect2, varscan2
- CEACAM18 | c.513T>C p.N171= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as COSV67282545; called by muse, mutect2, varscan2
- CFAP70 | c.84T>C p.T28= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV60282073; called by muse, mutect2, varscan2
- CLEC16A | c.270C>T p.G90= | Silent (SNP) | VAF 101/383 reads (26%) | catalogued as COSV68498778; called by muse, mutect2, varscan2
- CRB1 | c.1191C>T p.D397= | Silent (SNP) | VAF 95/320 reads (30%) | catalogued as rs758897056, COSV100958066, COSV66329251; called by muse, mutect2, varscan2
- CYP2F1 | c.1053G>C p.A351= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58527064; called by muse, mutect2, varscan2
- DLGAP5 | c.1239C>T p.V413= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV55962694; called by muse, varscan2
- DMRT3 | c.837G>A p.V279= | Silent (SNP) | VAF 77/170 reads (45%) | catalogued as rs769489578, COSV51903463; called by muse, varscan2
- EPG5 | c.2061G>T p.L687= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as COSV56347352; called by muse, mutect2, varscan2
- HEPHL1 | c.2214C>A p.A738= | Silent (SNP) | VAF 55/216 reads (25%) | catalogued as COSV59889614; called by muse, mutect2, varscan2
- HTN1 | c.117A>T p.S39= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV55894756; called by muse, mutect2, varscan2
- IGSF9 | c.1596T>C p.D532= (on ENST00000368094 / NM_001135050.2; = p.D516= on NM_020789.4) | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as COSV63639379; called by muse, mutect2, varscan2
- ITGA8 | c.1161T>C p.G387= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV65226887; called by muse, mutect2, varscan2
- KALRN | c.2889C>T p.A963= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as rs771065024, COSV53758729; called by muse, mutect2, varscan2
- KCNH3 | c.2070G>T p.P690= | Silent (SNP) | VAF 66/256 reads (26%) | catalogued as COSV57790087, COSV57793209; called by muse, mutect2, varscan2
- KCNH6 | c.1782T>C p.A594= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV59001843; called by muse, mutect2, varscan2
- LIG4 | c.2385G>T p.L795= | Silent (SNP) | VAF 76/146 reads (52%) | catalogued as COSV63596733; called by muse, mutect2, varscan2
- LPCAT1 | c.579G>T p.R193= | Silent (SNP) | VAF 132/444 reads (30%) | catalogued as COSV52036618; called by muse, mutect2, varscan2
- MUC16 | c.30741A>T p.P10247= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV67455957; called by muse, mutect2, varscan2
- NAF1 | c.978G>A p.R326= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV56803802; called by muse, mutect2, varscan2
- NCAPD3 | c.3447C>T p.L1149= | Silent (SNP) | VAF 72/266 reads (27%) | catalogued as COSV73244844; called by muse, mutect2, varscan2
- NEB | c.17031C>G p.V5677= | Silent (SNP) | VAF 197/795 reads (25%) | catalogued as COSV50806680, COSV50916691; called by muse, mutect2, varscan2
- OR8K5 | c.327C>A p.I109= | Silent (SNP) | VAF 84/324 reads (26%) | catalogued as COSV57888343; called by muse, mutect2, varscan2
- PLA2G4F | c.465G>A p.L155= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as rs747586112, COSV51826195; called by muse, mutect2, varscan2
- PLEKHH2 | c.1194A>T p.S398= | Silent (SNP) | VAF 61/223 reads (27%) | catalogued as COSV56751538; called by muse, mutect2, varscan2
- PLXND1 | c.3384G>A p.G1128= | Silent (SNP) | VAF 157/242 reads (65%) | catalogued as rs775485525, COSV60711094; called by muse, mutect2, varscan2
- PTPRN | c.771T>C p.P257= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV55346795; called by muse, mutect2, varscan2
- PYGO1 | c.666T>C p.F222= | Silent (SNP) | VAF 106/425 reads (25%) | catalogued as COSV57347155; called by muse, mutect2, varscan2
- QDPR | c.91C>A p.R31= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55549710, COSV99845858; called by muse, mutect2
- RFPL2 | c.720C>T p.R240= | Silent (SNP) | VAF 172/370 reads (46%) | catalogued as rs773791782, COSV50709603; called by muse, mutect2, varscan2
- SEMA5B | c.1968C>T p.I656= | Silent (SNP) | VAF 69/303 reads (23%) | catalogued as COSV52094450; called by muse, mutect2, varscan2
- SLC12A3 | c.3042C>T p.N1014= (on ENST00000563236 / NM_001126108.2; = p.N1023= on NM_000339.3) | Silent (SNP) | VAF 56/310 reads (18%) | catalogued as rs149767532, CM078135; called by muse, mutect2, varscan2
- SLC44A2 | c.1125C>T p.I375= | Silent (SNP) | VAF 93/305 reads (30%) | catalogued as rs748937282, COSV59835828; called by muse, mutect2, varscan2
- TEX44 | c.897C>T p.T299= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as COSV58354814; called by muse, mutect2, varscan2
- TTN | c.777G>T p.P259= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV59964842; called by muse, mutect2, varscan2
- ZFHX4 | c.5238G>A p.T1746= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV50651121, COSV51492261; called by muse, mutect2, varscan2
- ZFP90 | c.93C>T p.V31= | Silent (SNP) | VAF 82/374 reads (22%) | catalogued as rs376978594; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1225G>A | Intron (SNP) | VAF 80/249 reads (32%) | catalogued as rs369288906; called by muse, mutect2, varscan2
- CFAP61 | c.567-5360G>C | Intron (SNP) | VAF 63/280 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.7827G>A | RNA (SNP) | VAF 76/320 reads (24%) | catalogued as COSV100602436, COSV61769758; called by muse, mutect2, varscan2
- DCHS2 | n.1907C>T | RNA (SNP) | VAF 37/132 reads (28%) | catalogued as COSV59722046; called by muse, mutect2, varscan2
- GLYATL1 | c.-55C>T | 5'UTR (SNP) | VAF 41/139 reads (29%) | catalogued as COSV100265399, COSV55608441; called by muse, mutect2, varscan2
- PREX2 | c.2716-2807C>A | Intron (SNP) | VAF 55/221 reads (25%) | catalogued as COSV99908020; called by muse, mutect2, varscan2
- RASSF5 | c.579+19289G>T | Intron (SNP) | VAF 47/155 reads (30%) | catalogued as COSV100456298; called by muse, mutect2, varscan2
